Somatic mutation profile of tumor specimen TCGA-39-5037-01A (aliquot TCGA-39-5037-01A-01D-1441-08) from TCGA case TCGA-39-5037, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.3 years (23,868 days).
Specimen TCGA-39-5037-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30e91827-49b6-494e-a8f8-98379ce9af17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5037-11A (Solid Tissue Normal), aliquot TCGA-39-5037-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a15655e5-a905-4974-b7fe-11402d03e59e

The open-access MAF lists 249 somatic variants for this specimen: 186 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 57, Nonsense Mutation 10, Frame Shift Del 7, Splice Site 6, RNA 3, Intron 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 60/92 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC098582.1 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52017670; called by muse, mutect2, varscan2
- ACADL | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV52052203; called by muse, mutect2, varscan2
- ADGRB3 | c.3308G>T p.C1103F | Missense Mutation (SNP) | VAF 184/399 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53235279; called by muse, mutect2, varscan2
- ADGRE1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 122/336 reads (36%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.543); catalogued as COSV51672247, COSV99165117; called by muse, mutect2, varscan2
- ADSS1 | c.1073+1G>T p.X358_splice | Splice Site (SNP) | VAF 74/137 reads (54%) | catalogued as COSV58272068, COSV58273460; called by muse, mutect2, varscan2
- AFF3 | c.2533C>G p.L845V | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV57841454, COSV57879705; called by muse, mutect2, varscan2
- AHNAK | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 105/205 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.371); catalogued as rs781648735, COSV57204309; called by muse, mutect2, varscan2
- AK9 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.151); catalogued as COSV53419799; called by muse, mutect2, varscan2
- ALKBH8 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV52833449; called by muse, mutect2, varscan2
- AOX1 | c.3113T>C p.V1038A | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV53495396; called by muse, mutect2, varscan2
- ARHGAP45 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV54024447, COSV54024651; called by muse, mutect2, varscan2
- ARID1A | c.6210G>T p.Q2070H | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV61372297; called by muse, mutect2, varscan2
- ARNTL | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1434856001, COSV62985303; called by muse, mutect2, varscan2
- ASB17 | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV52409368; called by muse, mutect2, varscan2
- ASB18 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV58232546; called by muse, mutect2, varscan2
- ATP12A | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201403471, COSV54512664; called by muse, mutect2, varscan2
- ATP8B4 | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52709648; called by muse, mutect2, varscan2
- ATP8B4 | c.3080G>T p.G1027V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV52709659; called by muse, mutect2, varscan2
- BRCA1 | c.2333G>A p.G778D | Missense Mutation (SNP) | VAF 161/397 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.173); catalogued as rs730881483, COSV58784283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf71 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60504704, COSV60513564; called by muse, mutect2, varscan2
- CACNG7 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV55813071, COSV55814472; called by muse, mutect2, varscan2
- CALN1 | c.111G>T p.E37D (on ENST00000329008 / NM_001017440.3; = p.E79D on NM_031468.4) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV61120667; called by muse, mutect2, varscan2
- CBX8 | c.964C>G p.R322G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53935493; called by muse, mutect2, varscan2
- CCDC151 | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV62697238; called by muse, mutect2, varscan2
- CCDC27 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53898525; called by muse, mutect2, varscan2
- CDH10 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570760; called by muse, mutect2, varscan2
- CDH18 | c.1983A>C p.E661D | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV56903233; called by muse, mutect2, varscan2
- CDH9 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1409947188, COSV50253190, COSV50259461; called by muse, mutect2, varscan2
- CHD7 | c.3142G>T p.G1048W | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71107358; called by muse, mutect2, varscan2
- CHST2 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58884759, COSV58887118; called by muse, mutect2, varscan2
- CIR1 | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 178/479 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.361); catalogued as COSV59595210; called by muse, mutect2, varscan2
- DCUN1D1 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as COSV53043710; called by muse, mutect2
- DDX60L | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52708915; called by muse, mutect2, varscan2
- DENND2A | c.1832T>G p.I611S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52047945; called by muse, mutect2, varscan2
- DHX32 | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52938348; called by muse, mutect2, varscan2
- DISP3 | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as COSV53821037, COSV53834239; called by muse, mutect2, varscan2
- DNAH7 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV56752953; called by muse, mutect2, varscan2
- DNAH8 | c.2910G>T p.K970N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as rs763348835, COSV59426579; called by muse, mutect2, varscan2
- DNAH9 | c.11389G>A p.A3797T | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV52335287; called by muse, mutect2, varscan2
- DOCK2 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV56943260; called by muse, mutect2, varscan2
- DRD2 | c.1175C>A p.T392K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60754478; called by muse, mutect2
- DSC1 | c.2222C>A p.P741H | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57141994; called by muse, mutect2, varscan2
- DYSF | c.4762T>C p.F1588L | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.309); catalogued as COSV50270135; called by muse, mutect2, varscan2
- EMCN | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV56456789; called by muse, mutect2, varscan2
- EPG5 | c.5902C>A p.L1968I | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV56344881; called by muse, mutect2, varscan2
- ERBB4 | c.87T>A p.C29* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV53504215, COSV53513374; called by muse, mutect2, varscan2
- EVI5 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63278586; called by muse, mutect2, varscan2
- EVI5L | c.553-2A>G p.X185_splice | Splice Site (SNP) | VAF 29/95 reads (31%) | catalogued as COSV54483891; called by muse, mutect2, varscan2
- FAM135B | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV52706687; called by muse, mutect2, varscan2
- FAM160B1 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV65087293; called by muse, mutect2, varscan2
- FAM83D | c.1417T>G p.S473A | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV54156588; called by muse, mutect2, varscan2
- FAT2 | c.4714A>G p.T1572A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV55813958; called by muse, mutect2, varscan2
- FRMPD1 | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV66699237; called by muse, mutect2, varscan2
- FUT5 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV53134870; called by muse, mutect2, varscan2
- GADL1 | c.1065A>T p.K355N | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV56975277; called by muse, mutect2, varscan2
- GBA3 | c.1264A>T p.N422Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72437863; called by muse, mutect2, varscan2
- GOLIM4 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.634); catalogued as rs1364514152, COSV58328004; called by muse, mutect2, varscan2
- GPR35 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs376265458, COSV60576980; called by muse, mutect2, varscan2
- GRID2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as COSV56175419; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1554348298, COSV56084554; called by muse, mutect2, varscan2
- GYPC | c.105A>C p.A35= | Splice Region (SNP) | VAF 66/101 reads (65%) | catalogued as rs1237700223, COSV52145058; called by muse, mutect2, varscan2
- HRNR | c.3316G>A p.G1106S | Missense Mutation (SNP) | VAF 129/407 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.672); catalogued as rs1368681526, COSV100913054; called by muse, mutect2, varscan2
- HSPA2 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV55968831, COSV55969545; called by muse, mutect2, varscan2
- IGHMBP2 | c.1028C>G p.T343S | Missense Mutation (SNP) | VAF 110/157 reads (70%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV54820197; called by muse, mutect2, varscan2
- IGKV2-24 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 93/144 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1277829251; called by muse, mutect2, varscan2
- IL1R2 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753591681, COSV60205773; called by muse, mutect2, varscan2
- IMMP2L | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59220111; called by muse, mutect2, varscan2
- IQGAP2 | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as rs373704383; called by muse, mutect2, varscan2
- ISX | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV58085600; called by muse, mutect2, varscan2
- ITGAD | c.1708-2A>T p.X570_splice | Splice Site (SNP) | VAF 50/152 reads (33%) | catalogued as COSV66756851; called by muse, mutect2, varscan2
- ITGAX | c.2060G>T p.S687I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV51641882; called by muse, varscan2
- ITPR2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV67265025; called by muse, mutect2
- KMT2C | c.4430A>G p.N1477S | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs777432725, COSV51308496; called by muse, mutect2, varscan2
- LAMA5 | c.5257A>G p.T1753A | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53353338; called by muse, mutect2, varscan2
- LHCGR | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0.157); catalogued as COSV54292898; called by muse, mutect2, varscan2
- LMLN | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 269/368 reads (73%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV57598037; called by muse, mutect2, varscan2
- LPAR3 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 128/225 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV65452722; called by muse, mutect2, varscan2
- LRRC75B | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV50638192; called by muse, mutect2, varscan2
- LTBP2 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1300214460, COSV56205105; called by muse, mutect2, varscan2
- MAP1B | c.2426T>A p.M809K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57094062; called by muse, mutect2, varscan2
- MCHR2 | c.968G>T p.R323I | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV55999835, COSV56002651; called by muse, mutect2, varscan2
- MYH2 | c.2872A>T p.K958* | Nonsense Mutation (SNP) | VAF 71/193 reads (37%) | catalogued as COSV99819411; called by muse, mutect2, varscan2
- MYH4 | c.2524C>A p.P842T | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55112646; called by muse, mutect2, varscan2
- MYOM2 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373509557; called by muse, mutect2, varscan2
- NAALAD2 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.685); catalogued as COSV58958829, COSV58959243; called by muse, mutect2, varscan2
- NCKAP5 | c.5299C>T p.Q1767* | Nonsense Mutation (SNP) | VAF 55/114 reads (48%) | catalogued as rs559275412, COSV58428728; called by muse, mutect2, varscan2
- NCKAP5L | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); catalogued as COSV60127644; called by muse, mutect2, varscan2
- NCL | c.798_800del p.E271del | In Frame Del (DEL) | VAF 19/138 reads (14%) | catalogued as rs750970013; called by pindel, varscan2
- NDNF | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 129/214 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.159); catalogued as rs201892645, COSV65632645; called by muse, mutect2, varscan2
- NOTCH1 | c.6058G>C p.D2020H | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53030168, COSV53059785; called by muse, mutect2, varscan2
- NSMCE2 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54894294; called by muse, mutect2, varscan2
- NUP210L | c.2006C>A p.S669Y | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55142046; called by muse, mutect2, varscan2
- NUTM1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV61546009, COSV61547442; called by muse, mutect2, varscan2
- OR10AG1 | c.740C>G p.T247S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV56631571; called by muse, mutect2, varscan2
- OR10G9 | c.564T>A p.C188* | Nonsense Mutation (SNP) | VAF 28/292 reads (10%) | catalogued as COSV66685774; called by muse, mutect2
- OR10R2 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 75/631 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV63768506, COSV63768843; called by muse, mutect2, varscan2
- OR11H4 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs763601774, COSV59559770; called by muse, mutect2, varscan2
- OR1J4 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 98/178 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61589594, COSV61590018; called by muse, mutect2, varscan2
- OR2M2 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 98/478 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV62897726, COSV62897788; called by muse, varscan2
- OR2Z1 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60691720; called by muse, mutect2, varscan2
- OR3A2 | c.884A>T p.N295I | Missense Mutation (SNP) | VAF 71/99 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68694934, COSV68695217; called by muse, mutect2, varscan2
- OR4C11 | c.333T>G p.F111L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV56352253; called by muse, mutect2
- OR8J1 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57316671; called by muse, mutect2, varscan2
- OR8J3 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56879492; called by muse, mutect2
- OR8K3 | c.887T>A p.V296E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV57130824; called by muse, mutect2, varscan2
- PAQR9 | c.854T>A p.V285E | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV61417626; called by muse, mutect2
- PAQR9 | c.474C>G p.Y158* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV61417590, COSV61417633; called by muse, mutect2, varscan2
- PAQR9 | c.333C>A p.D111E | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as COSV61417639; called by muse, mutect2, varscan2
- PDCD11 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV63933099; called by muse, mutect2, varscan2
- PDZRN4 | c.1299C>A p.S433R (on ENST00000402685 / NM_001164595.2; = p.S175R on NM_013377.4) | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54192722, COSV54197111; called by muse, mutect2, varscan2
- PHKB | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV54514947; called by muse, mutect2, varscan2
- PI15 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs772197197, COSV52639690; called by muse, mutect2, varscan2
- PIK3CD | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63127195; called by muse, mutect2, varscan2
- PKHD1 | c.9010G>C p.V3004L | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV61861729; called by muse, mutect2, varscan2
- PNMA2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV72908459; called by muse, mutect2
- PRDM10 | c.3327A>T p.Q1109H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV58799441; called by muse, mutect2, varscan2
- PRKAR2B | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as rs1477864517, COSV55922472; called by muse, mutect2, varscan2
- PTCHD3 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV71256311; called by muse, mutect2, varscan2
- RAB3C | c.255C>G p.D85E | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51431759; called by muse, mutect2, varscan2
- REG1B | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59304482, COSV59307204, COSV59307463; called by muse, mutect2, varscan2
- REV1 | c.291T>A p.N97K | Missense Mutation (SNP) | VAF 170/291 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV51481985; called by muse, mutect2, varscan2
- RIMS2 | c.4495A>T p.T1499S (on ENST00000666250 / NM_001348490.2; = p.T1070S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51654812; called by muse, mutect2, varscan2
- RPS6KA6 | c.2044T>A p.W682R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53116385; called by muse, mutect2, varscan2
- RSU1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as rs773241755, COSV61708679, COSV61709094; called by muse, mutect2, varscan2
- RXFP1 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100313968, COSV57046929; called by muse, mutect2, varscan2
- RYR2 | c.376A>G p.S126G | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1470035636, COSV63663901; called by muse, mutect2
- RYR2 | c.11678C>A p.S3893Y | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63663906; called by muse, mutect2, varscan2
- SATB2 | c.1826A>G p.D609G | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.432); catalogued as COSV53478605; called by muse, mutect2, varscan2
- SCIN | c.1625T>G p.V542G (on ENST00000297029 / NM_001112706.3; = p.V295G on NM_033128.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99764521; called by muse, varscan2
- SCRT1 | c.42del p.F15Sfs*192 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV59781785; called by mutect2, pindel
- SCYL2 | c.775G>C p.V259L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV62567689; called by muse, mutect2, varscan2
- SEMG2 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV65647201; called by muse, mutect2
- SENP5 | c.2034G>T p.K678N | Missense Mutation (SNP) | VAF 108/155 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60206105; called by muse, mutect2, varscan2
- SFRP4 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52258301; called by muse, mutect2, varscan2
- SIAE | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV55013207; called by muse, mutect2, varscan2
- SKIV2L | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV64810225; called by muse, mutect2, varscan2
- SLAIN2 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV51904232; called by muse, mutect2, varscan2
- SLC12A9 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV51931452; called by muse, mutect2, varscan2
- SLC29A1 | c.864+1G>C p.X288_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as rs75037270, COSV57577366, COSV57579887; called by muse, mutect2, varscan2
- SLC39A12 | c.1760-1G>T p.X587_splice (on ENST00000377369 / NM_001145195.2; = p.X550_splice on NM_152725.3) | Splice Site (SNP) | VAF 28/170 reads (16%) | catalogued as COSV66195330; called by muse, mutect2, varscan2
- SLC4A10 | c.1264G>A p.D422N (on ENST00000446997 / NM_001354461.2; = p.D392N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55765431, COSV55781650; called by muse, mutect2, varscan2
- SLK | c.1844A>T p.K615I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59823874; called by muse, mutect2, varscan2
- SMARCA4 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs763471007, COSV60787137, COSV60790004; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMIM8 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs140990223; called by muse, mutect2, varscan2
- ST8SIA2 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 110/358 reads (31%) | PolyPhen probably damaging (0.981); catalogued as COSV51567097; called by muse, mutect2, varscan2
- SULT2A1 | c.148T>A p.L50M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.243); catalogued as COSV55764207; called by muse, mutect2, varscan2
- SYNCRIP | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV62286802; called by muse, mutect2, varscan2
- SYNE1 | c.21892G>T p.D7298Y (on ENST00000367255 / NM_182961.4; = p.D7227Y on NM_033071.3) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1295747846, COSV54912766; called by muse, mutect2, varscan2
- SYNE1 | c.13996G>A p.V4666I (on ENST00000367255 / NM_182961.4; = p.V4595I on NM_033071.3) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54912807; called by muse, mutect2, varscan2
- SYVN1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53694670; called by muse, mutect2, varscan2
- TECTA | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as rs376745254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEKT4 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs201231094, COSV54623053; called by muse, mutect2, varscan2
- TESMIN | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as COSV54831428, COSV54832498; called by muse, mutect2, varscan2
- TLR4 | c.1051A>T p.K351* (on ENST00000355622 / NM_138554.5; = p.K311* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as COSV62922457; called by muse, mutect2, varscan2
- TMED8 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53625329, COSV53627013; called by muse, mutect2, varscan2
- TPTE2 | c.974-2A>G p.X325_splice (on ENST00000400230 / NM_199254.2; = p.X248_splice on NM_130785.3) | Splice Site (SNP) | VAF 33/54 reads (61%) | catalogued as rs749029032, COSV55016473, COSV55030008; called by muse, mutect2, varscan2
- TRPS1 | c.2608T>A p.Y870N (on ENST00000220888 / NM_001330599.2; = p.Y883N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as rs1039993281, COSV55227677; called by muse, mutect2, varscan2
- TRRAP | c.8905A>G p.T2969A (on ENST00000359863 / NM_001244580.1; = p.T2951A on NM_003496.3) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV62839363; called by muse, mutect2, varscan2
- TTC33 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV61802295; called by muse, mutect2, varscan2
- TTLL5 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.345); catalogued as COSV54028332; called by muse, mutect2, varscan2
- TTN | c.20554A>T p.N6852Y (on ENST00000591111; = p.N5925Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | PolyPhen benign (0.053); catalogued as COSV59899711; called by muse, mutect2, varscan2
- UACA | c.1114A>G p.R372G | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV59853446; called by muse, mutect2, varscan2
- UBR2 | c.2907A>G p.I969M | Missense Mutation (SNP) | VAF 223/404 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs138557643; called by muse, mutect2, varscan2
- WIPF1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV55811568; called by muse, mutect2, varscan2
- WNK1 | c.3985A>G p.T1329A (on ENST00000315939 / NM_018979.4; = p.T1082A on NM_014823.3) | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs764193532, COSV60026033; called by muse, mutect2, varscan2
- XPO5 | c.2671A>T p.M891L | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV54827537; called by muse, mutect2, varscan2
- ZCCHC7 | c.1300T>C p.W434R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV60954610; called by muse, mutect2, varscan2
- ZFP37 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.012); catalogued as COSV65285918; called by muse, mutect2, varscan2
- ZGRF1 | c.2248T>C p.C750R | Missense Mutation (SNP) | VAF 104/144 reads (72%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52199047; called by muse, mutect2, varscan2
- ZMYM5 | c.742A>G p.K248E | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61987332; called by muse, mutect2, varscan2
- ZNF266 | c.691A>G p.M231V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs745506541, COSV63221504; called by muse, mutect2, varscan2
- ZNF320 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV67087587; called by mutect2, varscan2
- ZNF502 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV56072504; called by muse, mutect2, varscan2
- ZNF596 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV57652901; called by muse, mutect2, varscan2
- ZNF677 | c.1475G>T p.C492F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61719369; called by muse, mutect2, varscan2
- ZNF91 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56080821, COSV56087997; called by muse, mutect2, varscan2
- CNTN5 | c.1516del p.Q506Kfs*23 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.249del p.R83Sfs*? | Frame Shift Del (DEL) | VAF 34/170 reads (20%) | called by mutect2, varscan2
- KATNAL2 | c.216del p.M73Wfs*9 | Frame Shift Del (DEL) | VAF 55/184 reads (30%) | called by mutect2, pindel, varscan2
- LRRN2 | c.403del p.H135Tfs*43 | Frame Shift Del (DEL) | VAF 99/276 reads (36%) | called by mutect2, pindel, varscan2
- NEIL3 | c.882_884delinsAA p.R295Kfs*4 | Frame Shift Del (DEL) | VAF 47/132 reads (36%) | called by pindel, varscan2*
- OR11H12 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, varscan2
- RFTN1 | c.156dup p.G53Wfs*12 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- TRGV4 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ZNF804A | c.3212del p.P1071Qfs*25 | Frame Shift Del (DEL) | VAF 41/149 reads (28%) | called by mutect2, pindel, varscan2
- A2M | c.525C>T p.I175= | Silent (SNP) | VAF 113/228 reads (50%) | catalogued as rs761730698, COSV59383213; called by muse, mutect2, varscan2
- ANK3 | c.6225G>A p.Q2075= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV55045161; called by muse, mutect2, varscan2
- ANO5 | c.849C>T p.F283= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as COSV61082279; called by muse, mutect2, varscan2
- CASP8AP2 | c.2892G>A p.R964= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV52745359; called by muse, mutect2, varscan2
- CCDC116 | c.483T>C p.H161= | Silent (SNP) | VAF 86/185 reads (46%) | catalogued as COSV53037171; called by muse, mutect2, varscan2
- CCDC40 | c.3132C>T p.F1044= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs369736890; called by muse, mutect2
- CFAP70 | c.93C>T p.T31= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV60281106; called by muse, mutect2, varscan2
- CHD7 | c.7896C>T p.N2632= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV71107363; called by muse, mutect2, varscan2
- CNTNAP2 | c.444C>T p.H148= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs750661428, COSV62143240, COSV62147854; called by muse, mutect2, varscan2
- CSMD3 | c.10392C>A p.P3464= (on ENST00000297405 / NM_001363185.1; = p.P3295= on NM_052900.3) | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV52108019; called by muse, mutect2, varscan2
- CSMD3 | c.4179C>T p.L1393= (on ENST00000297405 / NM_001363185.1; = p.L1289= on NM_052900.3) | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV52108034; called by muse, mutect2, varscan2
- CYP2C8 | c.1227T>C p.P409= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV64876125; called by muse, mutect2, varscan2
- DCSTAMP | c.666C>A p.L222= | Silent (SNP) | VAF 68/178 reads (38%) | catalogued as rs755292234, COSV52576241, COSV52576525, COSV99886953; called by muse, mutect2, varscan2
- EFEMP2 | c.1215G>A p.V405= | Silent (SNP) | VAF 85/127 reads (67%) | catalogued as COSV57259185; called by muse, mutect2, varscan2
- ERCC6 | c.3405A>G p.T1135= | Silent (SNP) | VAF 58/136 reads (43%) | catalogued as COSV63387986; called by muse, varscan2
- FAM135B | c.3024C>A p.S1008= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV52706664; called by muse, mutect2, varscan2
- FCMR | c.334C>A p.R112= | Silent (SNP) | VAF 82/182 reads (45%) | catalogued as COSV65567108; called by muse, mutect2, varscan2
- FREM1 | c.1908G>T p.V636= | Silent (SNP) | VAF 51/85 reads (60%) | catalogued as COSV66518181; called by muse, mutect2, varscan2
- GATA4 | c.810C>G p.S270= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100632950, COSV58732431, COSV58734910; called by muse, mutect2, varscan2
- GRN | c.1110C>T p.S370= | Silent (SNP) | VAF 69/149 reads (46%) | catalogued as COSV50006212; called by muse, mutect2, varscan2
- IGLL5 | c.477G>A p.A159= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1238375606, COSV66535207; called by muse, mutect2
- IGLV3-19 | c.270C>A p.S90= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs532332815; called by muse, mutect2, varscan2
- INPP5K | c.1227G>A p.E409= | Silent (SNP) | VAF 57/85 reads (67%) | catalogued as rs200875024, COSV57440018; called by muse, mutect2, varscan2
- IQCF3 | c.246G>T p.L82= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV71309436; called by muse, mutect2, varscan2
- ITGA7 | c.3336G>A p.A1112= (on ENST00000555728; = p.A1068= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs759134989, COSV57691557; called by muse, mutect2
- KIAA1549 | c.339G>A p.P113= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs1177918017, COSV54306137; called by muse, mutect2
- KLK7 | c.567G>C p.L189= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV58343927; called by muse, mutect2, varscan2
- KRT1 | c.1101T>C p.A367= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs755016557, COSV52865053; called by muse, varscan2
- L1CAM | c.435C>A p.P145= | Silent (SNP) | VAF 53/73 reads (73%) | catalogued as COSV62826927; called by muse, mutect2, varscan2
- LRRC14 | c.1353C>T p.S451= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV52877841; called by muse, mutect2, varscan2
- MDN1 | c.1296G>A p.L432= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV65517489; called by muse, mutect2, varscan2
- MMP21 | c.9C>T p.A3= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs149511576; called by muse, mutect2, varscan2
- MRPL18 | c.279T>C p.L93= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV51703884; called by muse, mutect2, varscan2
- NAV3 | c.1180C>A p.R394= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as COSV57063271, COSV57075729; called by muse, mutect2, varscan2
- NUP153 | c.1470T>C p.S490= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV50446294; called by muse, mutect2, varscan2
- OGDH | c.2907G>T p.V969= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as COSV56045847; called by muse, mutect2, varscan2
- OR14K1 | c.594G>T p.V198= | Silent (SNP) | VAF 112/256 reads (44%) | catalogued as rs766512597, COSV99314989; called by muse, mutect2, varscan2
- OR2M2 | c.510G>T p.G170= | Silent (SNP) | VAF 97/478 reads (20%) | catalogued as COSV62897841, COSV62898202; called by muse, varscan2
- PAPPA2 | c.3576T>G p.A1192= | Silent (SNP) | VAF 100/165 reads (61%) | catalogued as COSV62791202; called by muse, mutect2, varscan2
- PCDHA13 | c.297C>T p.S99= | Silent (SNP) | VAF 55/277 reads (20%) | catalogued as rs782122682, COSV56479550; called by muse, mutect2, varscan2
- PGAP4 | c.816G>T p.L272= | Silent (SNP) | VAF 118/181 reads (65%) | catalogued as COSV66387221; called by muse, mutect2, varscan2
- RASAL2 | c.2466G>A p.K822= | Silent (SNP) | VAF 85/168 reads (51%) | catalogued as COSV62710046; called by muse, mutect2, varscan2
- RBFOX1 | c.42A>C p.A14= | Silent (SNP) | VAF 53/222 reads (24%) | catalogued as COSV60946746; called by muse, mutect2, varscan2
- SCN2A | c.645G>C p.A215= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as rs370724112, COSV51833008, COSV51835837; called by muse, mutect2, varscan2
- SCRN2 | c.861C>T p.A287= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as COSV51634988; called by muse, mutect2, varscan2
- SH3RF1 | c.993C>T p.L331= | Silent (SNP) | VAF 102/257 reads (40%) | catalogued as COSV52918554; called by muse, mutect2, varscan2
- SLC17A4 | c.735C>T p.L245= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV100930666, COSV64955654; called by muse, mutect2, varscan2
- SLC35F5 | c.201G>A p.R67= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV55516959; called by muse, mutect2, varscan2
- SLC6A5 | c.615G>T p.V205= | Silent (SNP) | VAF 17/237 reads (7%) | catalogued as COSV54223804; called by muse, mutect2
- STXBP1 | c.825G>T p.R275= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV64812126; called by muse, mutect2, varscan2
- TCEAL2 | c.414C>A p.A138= | Silent (SNP) | VAF 53/92 reads (58%) | catalogued as COSV61197159; called by muse, mutect2, varscan2
- TFF3 | c.81G>A p.L27= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs776182306, COSV52294045; called by muse, mutect2, varscan2
- TMEM132D | c.1905T>A p.L635= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV67158790; called by muse, mutect2, varscan2
- TRIM72 | c.387C>G p.L129= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs777546373, COSV100265494, COSV57250661; called by muse, mutect2, varscan2
- ZBED4 | c.696T>G p.S232= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV53463838; called by muse, mutect2, varscan2
- ZC3H7B | c.27C>T p.D9= | Silent (SNP) | VAF 28/245 reads (11%) | catalogued as rs978282466, COSV60960574; called by muse, mutect2, varscan2
- ZNF264 | c.1152A>T p.A384= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV54040687; called by muse, mutect2, varscan2
- DHRS4L1 | n.63G>A | RNA (SNP) | VAF 23/41 reads (56%) | catalogued as rs778735858; called by muse, mutect2
- MIR588 | n.68C>T | RNA (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- OR1N2 | c.-2G>T | 5'UTR (SNP) | VAF 75/112 reads (67%) | catalogued as COSV65460226; called by muse, mutect2, varscan2
- PRB1 | c.101-1503C>A | Intron (SNP) | VAF 86/198 reads (43%) | catalogued as COSV53702502; called by muse, mutect2, varscan2
- SNORD115-15 | n.14G>T | RNA (SNP) | VAF 34/512 reads (7%) | called by muse, mutect2
- TRIM61 | c.526-2247C>A | Intron (SNP) | VAF 25/52 reads (48%) | catalogued as COSV61417555, COSV61418163; called by muse, mutect2, varscan2
